Gene-level copy-number profile of tumor specimen TCGA-25-1626-01A from TCGA case TCGA-25-1626, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.5 years (23,932 days).
Specimen TCGA-25-1626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e112fed6-8e4f-4bc6-9f93-d6c73ba9b223.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1626-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/263bf539-8a30-4240-b7ff-7e1e0f241e27

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,331; copy number 2: 27,952; copy number 3: 17,385; copy number 4: 8,647; copy number 5: 1,505.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1626-01): tumor purity 0.32, ploidy 2.61, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,505 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–8,218,911, 273 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:22,063,773–22,437,041, 1 gene, copy number 5 (within-gene range 4–5): ST8SIA1.
- chr12:22,395,088–23,251,499, 14 genes, copy number 5: AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:31,254,361–55,118,632, 601 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:39,731,255–41,261,766, 75 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–6,220,759, 196 genes, copy number 5 (broad region; genes not listed).
- chr20:31,368,601–38,337,505, 241 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:45,534,196–45,547,662, 1 gene, copy number 5 (within-gene range 4–5): EPPIN-WFDC6.
- chr20:45,540,626–49,096,960, 103 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,910. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
